Somatic mutation profile of tumor specimen TCGA-RD-A8NB-01A (aliquot TCGA-RD-A8NB-01A-12D-A397-08) from TCGA case TCGA-RD-A8NB, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 80.8 years (29,503 days).
Specimen TCGA-RD-A8NB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df34bc4e-4e51-49ab-b589-eca39947a8ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8NB-10A (Blood Derived Normal), aliquot TCGA-RD-A8NB-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1da4946-4916-4941-b7bf-e2ba730d9aca

The open-access MAF lists 686 somatic variants for this specimen: 513 protein-altering or splice-affecting, 157 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 357, Silent 157, Frame Shift Del 94, Nonsense Mutation 31, Splice Site 13, Frame Shift Ins 12, Intron 7, RNA 4, In Frame Del 3, Splice Region 2, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F5 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 11/115 reads (10%) | catalogued as rs757953549, CM980661, COSV100888970; ClinVar: likely pathogenic; called by muse, mutect2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- GCK | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193922317, CM970635, COSV60786559; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KARS1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1415687857, COSV56691858; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- LSM14A | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1370603291, COSV70884805; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.451del p.R151Afs*50 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | catalogued as rs1562689635, COSV56223909; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UGT1A1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139607673, CM983520; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3343A>C p.T1115P | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99685805; called by muse, mutect2
- ABRAXAS1 | c.474del p.G159Dfs*8 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1560574509; called by mutect2, pindel
- AC097636.1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs559038253, COSV71309693; called by muse, mutect2, varscan2
- ACP5 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV99520341; called by muse, mutect2
- ACSM3 | c.220-2A>G p.X74_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99184526; called by muse, mutect2
- ACTC1 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV99291875; called by muse, mutect2, varscan2
- ACTG1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1568060200, COSV100111948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTL7A | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs958184341, COSV61776249; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS12 | c.1975T>C p.F659L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100711020; called by muse, mutect2, varscan2
- ADCY9 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72556390, COSV99570063; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs764604854; called by mutect2, pindel, varscan2
- ADGRG2 | c.366del p.F122Lfs*21 (on ENST00000379869 / NM_001079858.3; = p.F119Lfs*21 on NM_005756.4) | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as COSV61341022; called by mutect2, pindel
- ADGRG4 | c.7478T>C p.I2493T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs771476689, COSV54949945, COSV99795617; called by muse, mutect2
- ADH7 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs549028723, COSV52923136; called by muse, mutect2, varscan2
- ADORA2A | c.680A>T p.K227M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100418049; called by muse, mutect2
- AHNAK2 | c.1976del p.K659Rfs*5 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | catalogued as rs1178630013; called by mutect2, varscan2
- AKAP1 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100027966; called by muse, mutect2, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2, varscan2
- AKT3 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99795506; called by muse, mutect2, varscan2
- AL662899.2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.241); catalogued as COSV101021741; called by muse, mutect2
- ALDH16A1 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766785153, COSV53194505; called by muse, mutect2, varscan2
- ANKAR | c.2893G>A p.V965I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99854291; called by muse, mutect2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs753570186; called by mutect2, varscan2
- ANXA6 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs762451507, COSV100636942; called by muse, mutect2, varscan2
- AP4M1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs746585330, COSV100384945; called by muse, mutect2
- ARAP3 | c.2257T>C p.F753L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV99499755; called by muse, mutect2, varscan2
- ARFGEF2 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV100904274; called by muse, mutect2, varscan2
- ARHGAP17 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.154); catalogued as rs771333518, COSV99253491; called by muse, mutect2, varscan2
- ARHGAP22 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144924707; called by mutect2, varscan2
- ARHGEF12 | c.1631T>C p.M544T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV100754945; called by muse, mutect2, varscan2
- ASH2L | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99166983; called by muse, mutect2
- ATAD2 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1461653121, COSV54883497, COSV99783855; called by muse, mutect2
- ATF7IP | c.2552C>A p.P851H | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV99661714; called by muse, mutect2, varscan2
- ATM | c.7681C>A p.L2561M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV53736178; called by muse, mutect2
- ATP10B | c.1442A>G p.Q481R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100469433; called by muse, mutect2, varscan2
- ATP13A5 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs138137992; called by muse, mutect2, varscan2
- ATP8B4 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV99465696; called by muse, mutect2, varscan2
- AUH | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445153680, COSV100342464; called by muse, mutect2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | catalogued as COSV62562863; called by mutect2, varscan2
- B3GALT5 | c.637T>C p.F213L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100563388; called by muse, mutect2, varscan2
- BCOR | c.4123C>T p.R1375W (on ENST00000378444 / NM_001123385.2; = p.R1341W on NM_017745.6) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV60700149; called by muse, mutect2
- BCORL1 | c.4075G>A p.A1359T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.233); catalogued as COSV99499682; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs752427670; called by mutect2, varscan2
- BIRC7 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV99416791; called by muse, mutect2
- BRD4 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752762666, COSV54584208; called by muse, mutect2, varscan2
- BRWD1 | c.3919del p.S1307Afs*19 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs1296036169; called by mutect2, pindel, varscan2
- BUB1B | c.2680A>G p.I894V | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99806953; called by muse, mutect2
- C10orf90 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs370672577; called by muse, mutect2, varscan2
- C15orf39 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs201514875, COSV100641353, COSV62297986; called by muse, mutect2, varscan2
- C2CD3 | c.3100T>C p.Y1034H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV100486775; called by muse, mutect2, varscan2
- C9orf43 | c.902A>G p.Q301R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV99928383; called by muse, mutect2, varscan2
- CACNA1C | c.915A>T p.A305= | Splice Region (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100219254; called by muse, mutect2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs765105588; called by mutect2, varscan2
- CBX1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99848158; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC88B | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1376515291, COSV100105461; called by muse, mutect2, varscan2
- CCKBR | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV100582961; called by muse, mutect2, varscan2
- CCR9 | c.236T>C p.V79A (on ENST00000357632 / NM_031200.3; = p.V67A on NM_006641.4) | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.101); catalogued as COSV100591704; called by muse, mutect2
- CDC73 | c.1565T>C p.M522T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV100813885; called by muse, mutect2, varscan2
- CDCA4 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100288208; called by muse, mutect2
- CDCA7 | c.275G>A p.R92H (on ENST00000347703 / NM_145810.3; = p.R171H on NM_031942.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV60719821; called by muse, mutect2, varscan2
- CDCA7L | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as rs767849344, COSV100179376; called by muse, mutect2, varscan2
- CEP104 | c.490-1G>T p.X164_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100986358; called by muse, mutect2
- CFAP54 | c.5014C>A p.L1672I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100733187; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs1561489348; called by pindel, varscan2
- CHMP3 | c.530T>C p.L177S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99806688; called by muse, mutect2, varscan2
- CHRNA3 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1295333312, COSV58775139; called by muse, mutect2, varscan2
- CHRNB2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs774455462; called by muse, mutect2, varscan2
- CLCNKA | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100510120; called by muse, mutect2
- CLCNKB | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65160215; called by muse, mutect2
- CLIP2 | c.2773G>A p.G925R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.809); catalogued as COSV56275226, COSV99791630; called by muse, mutect2, varscan2
- CNOT1 | c.2549G>A p.S850N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV99800308; called by mutect2, varscan2
- CNOT1 | c.2351G>A p.G784D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs890309345, COSV100409375; called by muse, mutect2, varscan2
- CNTN6 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610791; called by muse, mutect2
- CNTNAP5 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2, varscan2
- COL1A1 | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM090250, COSV99867306; called by muse, mutect2
- COLGALT1 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.147); catalogued as rs1203966034, COSV99395080; called by muse, mutect2, varscan2
- COLQ | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV101082231; called by muse, mutect2, varscan2
- COPG1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs767131343, COSV100135629; called by muse, mutect2, varscan2
- CPS1 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV99243121; called by muse, mutect2, varscan2
- CRB2 | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1051613061, COSV100749656; called by mutect2, varscan2
- CRTAM | c.224A>G p.H75R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs769625180, COSV99912038; called by muse, mutect2, varscan2
- CSF1R | c.1293G>A p.W431* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99642013; called by muse, mutect2
- CSF2RA | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs758879393, COSV100817754; called by muse, mutect2, varscan2
- CTDP1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99310657; called by muse, mutect2, varscan2
- CTSC | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs751326698, COSV57055961; called by muse, mutect2, varscan2
- CUZD1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs201662828, COSV100158837; called by muse, mutect2, varscan2
- CYP26B1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs144968323; called by mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV99245498; called by mutect2, pindel
- DCAF6 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs184187462, COSV56581616; called by muse, mutect2
- DCUN1D4 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1303403673, COSV58121847; called by muse, mutect2, varscan2
- DDX3X | c.779G>T p.G260V (on ENST00000399959; = p.G261V on NM_001356.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV101302447; called by muse, mutect2, varscan2
- DGKB | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1239237069, COSV51784985; called by muse, mutect2, varscan2
- DHX29 | c.2974C>T p.R992* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs865856124, COSV52418445; called by muse, mutect2, varscan2
- DIAPH1 | c.2947G>A p.V983I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV99526648; called by muse, mutect2, varscan2
- DIDO1 | c.5950C>T p.P1984S | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV99825988; called by muse, mutect2, varscan2
- DISP2 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779760492, COSV99140041; called by muse, mutect2, varscan2
- DLG2 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.439); catalogued as COSV99716306; called by muse, mutect2, varscan2
- DNAH10 | c.7915C>T p.R2639C (on ENST00000409039; = p.R2578C on NM_207437.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774602539, COSV69005161; called by muse, mutect2, varscan2
- DNAH8 | c.2626T>A p.S876T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100545554; called by muse, mutect2, varscan2
- DNAJC18 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as COSV100122143; called by muse, mutect2
- DPEP2 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.009); catalogued as rs267604603, COSV52054862; called by muse, mutect2, varscan2
- DPF2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565531873, COSV99361275; called by muse, mutect2, varscan2
- DPPA5 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs758222466, COSV64875459; called by muse, mutect2, varscan2
- DPYD | c.2788C>T p.Q930* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100929126; called by muse, mutect2, varscan2
- DSC2 | c.1891A>G p.T631A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99199655; called by muse, mutect2
- DSTN | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV99855174; called by muse, mutect2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs768937539; called by pindel, varscan2
- DZIP3 | c.27dup p.V10Cfs*15 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | catalogued as rs904107661; called by mutect2, pindel
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs746509911; called by mutect2, varscan2
- ECD | c.1705-1G>T p.X569_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100624773, COSV100624863; called by muse, mutect2
- EDEM1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56581262; called by muse, mutect2
- EEA1 | c.3733G>T p.A1245S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1565803959, COSV100467716; called by muse, mutect2
- EFL1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.416); catalogued as rs376049845; called by muse, mutect2, varscan2
- EIF2A | c.818dup p.N273Kfs*6 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs750490771; called by pindel, varscan2
- EIF2B5 | c.838T>A p.F280I (on ENST00000647909; = p.F272I on NM_003907.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99889286; called by muse, mutect2, varscan2
- EN2 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV52082662, COSV99818630; called by muse, mutect2, varscan2
- ENPP3 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV100717352; called by muse, mutect2
- EPHA3 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV60706249; called by mutect2, varscan2
- ERBB3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.697); catalogued as COSV57248597; called by muse, mutect2
- ERICH3 | c.1554G>T p.Q518H | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100444482; called by muse, mutect2
- ESPL1 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs746581481, COSV99229368; called by muse, mutect2, varscan2
- ETV6 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM1511684, COSV56766377; called by muse, mutect2
- EXO1 | c.2190del p.D731Tfs*4 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs752940417; called by mutect2, varscan2
- EXTL3 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV99594028; called by muse, mutect2, varscan2
- F8 | c.4046G>A p.R1349K | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100811560; called by muse, mutect2, varscan2
- FABP4 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs749437633, COSV56268878; called by muse, mutect2
- FAM47A | c.2036T>C p.F679S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100649914; called by muse, mutect2, varscan2
- FAM47A | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100649915, COSV60494624; called by muse, mutect2, varscan2
- FAM83E | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1202166849, COSV99572233; called by muse, mutect2
- FARP1 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768787362, COSV100130796; called by muse, mutect2, varscan2
- FARP1 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs765939276, COSV100130799; called by muse, mutect2
- FAT2 | c.6226T>C p.Y2076H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV99943026; called by muse, mutect2, varscan2
- FBL | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.375); catalogued as rs142991383; called by muse, mutect2, varscan2
- FBN2 | c.7659del p.F2554Lfs*57 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as rs748600284, COSV99331968; called by pindel, varscan2
- FBN3 | c.6688G>A p.G2230S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142411053; called by muse, mutect2, varscan2
- FCGBP | c.6610G>A p.A2204T | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs1325012784; called by muse, mutect2
- FEM1C | c.778del p.R260Efs*7 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as rs1561556190; called by mutect2, pindel, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLG2 | c.5633C>A p.S1878Y | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV101165897; called by muse, varscan2
- FLNA | c.7849T>C p.S2617P (on ENST00000369850 / NM_001110556.2; = p.S2609P on NM_001456.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100774737; called by muse, mutect2, varscan2
- FOSL2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1286334066, COSV53104255; called by muse, mutect2, varscan2
- FRAS1 | c.4633C>T p.P1545S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99352453; called by muse, mutect2, varscan2
- FREM1 | c.2176G>T p.V726L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV101084644; called by muse, mutect2, varscan2
- FTO | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs200201735, COSV67111046; called by mutect2, varscan2
- FUS | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV99568663; called by muse, mutect2, varscan2
- FYB2 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs767925458, COSV58585039; called by muse, mutect2, varscan2
- FYCO1 | c.2757G>T p.K919N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV99945711; called by muse, mutect2, varscan2
- G6PD | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99682432; called by muse, mutect2, varscan2
- GAA | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs780799275, COSV100163231; called by muse, mutect2, varscan2
- GALNT6 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1002613489, COSV100695479; called by muse, mutect2, varscan2
- GALNTL6 | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101487757; called by muse, mutect2, varscan2
- GEMIN4 | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.387); catalogued as COSV100021392; called by muse, mutect2, varscan2
- GEMIN5 | c.4093G>A p.A1365T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99593948; called by muse, mutect2
- GLB1L | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99850589; called by muse, mutect2, varscan2
- GLT8D1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1335432952, COSV99803832; called by muse, mutect2
- GP6 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117531; called by muse, mutect2
- GPR143 | c.592A>T p.M198L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV101102242; called by muse, mutect2, varscan2
- GPRIN1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs764198142, COSV56139472; called by muse, mutect2, varscan2
- GRIN2A | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100409968; called by muse, mutect2, varscan2
- GUCY2F | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99485047; called by mutect2, varscan2
- H1-3 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs1418051423, COSV99768759; called by muse, mutect2
- HAAO | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as COSV99685397; called by muse, mutect2, varscan2
- HDAC3 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV59498291; called by muse, mutect2, varscan2
- HEMK1 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99231680; called by muse, mutect2
- HERC2 | c.12922T>C p.C4308R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874086; called by muse, mutect2, varscan2
- HK1 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as rs760487849, COSV53854309; called by muse, mutect2, varscan2
- HNRNPH1 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV100270665; called by muse, mutect2, varscan2
- HOXA7 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.058); catalogued as COSV99636483; called by muse, mutect2, varscan2
- HSF4 | c.778C>T p.P260S (on ENST00000521374 / NM_001040667.3; = p.A264= on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs781742797, COSV99263531; called by muse, mutect2, varscan2
- IFNA17 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101303461; called by muse, mutect2, varscan2
- IFNAR2 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV99269982; called by muse, mutect2
- IGHV3-16 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.213); catalogued as rs370575595; called by muse, mutect2, varscan2
- IGLV2-14 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.282); catalogued as rs563003352; called by muse, mutect2, varscan2
- IL4R | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs749041212, COSV50160433; called by muse, mutect2, varscan2
- IMMT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV99607329; called by muse, mutect2
- IMPDH2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1275707815, COSV58247393; called by muse, mutect2, varscan2
- INAVA | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs933167224, COSV66256189; called by muse, mutect2, varscan2
- INTS2 | c.3224G>A p.S1075N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs207476529, COSV99248184; called by mutect2, varscan2
- INTU | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs990640805, COSV58869971; called by muse, mutect2
- ITGB2 | c.1685C>T p.T562I (on ENST00000302347; = p.T538I on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100185894; called by muse, mutect2, varscan2
- ITIH5 | c.2572G>T p.G858W | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99904742; called by muse, mutect2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs1226801045; called by mutect2, varscan2
- KATNIP | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99851186; called by muse, mutect2, varscan2
- KCND3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100137521; called by muse, mutect2, varscan2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs760505003; called by mutect2, varscan2
- KCNJ3 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54533558, COSV99715872; called by muse, mutect2
- KCNN3 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as rs368720064; called by mutect2, varscan2
- KCTD19 | c.1982G>A p.S661N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100430956; called by muse, mutect2, varscan2
- KIAA0930 | c.425C>T p.A142V (on ENST00000336156 / NM_001009880.2; = p.A147V on NM_015264.2) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1262641468, COSV52662124; called by muse, varscan2
- KIF16B | c.3692T>C p.L1231S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100734364; called by muse, mutect2
- KIF1A | c.3484C>T p.P1162S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs867593324, COSV100241107; called by mutect2, varscan2
- KIF21A | c.3284C>A p.P1095H (on ENST00000361418 / NM_001378440.1; = p.P1082H on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100735476; called by muse, mutect2, varscan2
- KIF4A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53452286; called by muse, mutect2
- KLF10 | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV99574779; called by muse, mutect2
- KRT1 | c.1786G>A p.G596S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.098); catalogued as rs1419572304, COSV52866764; called by muse, mutect2, varscan2
- KRT7 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100081576; called by muse, mutect2, varscan2
- KRT72 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs777794753, COSV99537291; called by mutect2, varscan2
- KRT74 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as rs148647777; called by muse, mutect2, varscan2
- LDHB | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs753313189, COSV100636389, COSV100636413; called by muse, mutect2, varscan2
- LHFPL1 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100914467; called by muse, mutect2
- LILRB1 | c.658G>A p.V220M (on ENST00000427581; = p.V184M on NM_006669.6) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs376597507, COSV61117652; called by muse, varscan2
- LMAN1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371193985; called by muse, mutect2
- LMO7 | c.2926T>C p.S976P (on ENST00000357063; = p.S657P on NM_005358.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58541660; called by muse, mutect2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs748712732; called by mutect2, varscan2
- LNPK | c.104del p.N35Ifs*12 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1443101323; called by pindel, varscan2
- LRP5 | c.2764G>A p.G922S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs773895575, COSV99592059; called by mutect2, varscan2
- LRRC4 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99975013; called by muse, mutect2, varscan2
- LRRN2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs369686045, COSV65783373; called by muse, mutect2, varscan2
- LSM14B | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99444259; called by muse, mutect2
- MAGED1 | c.2200T>G p.F734V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100431611; called by muse, mutect2
- MAGED2 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV99514584; called by muse, mutect2
- MAN2A2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100847874; called by muse, mutect2
- MAP10 | c.2908G>T p.D970Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101406509; called by muse, mutect2, varscan2
- MAPK3 | c.1098G>T p.Q366H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99531620; called by muse, mutect2, varscan2
- MAPKAP1 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs887892523, COSV99785049; called by muse, mutect2, varscan2
- MDC1 | c.1691T>C p.V564A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV100902825; called by muse, mutect2, varscan2
- MDK | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as COSV100551502; called by mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs746910913; called by mutect2, varscan2
- MDM2 | c.1197C>G p.D399E | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.098); catalogued as COSV99254585; called by muse, mutect2
- MED25 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs536678372, COSV100457464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEP1B | c.1886G>T p.R629M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99328888; called by muse, mutect2
- MGLL | c.152C>T p.A51V (on ENST00000398104 / NM_001003794.2; = p.A61V on NM_007283.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV99411910; called by muse, mutect2, varscan2
- MGP | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99967132; called by muse, mutect2, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs778232663; called by mutect2, varscan2
- MOGS | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1484924781, COSV99270544; called by mutect2, varscan2
- MPP4 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100206925; called by muse, mutect2, varscan2
- MRPL24 | c.52del p.H18Ifs*6 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs760797871; called by mutect2, pindel, varscan2
- MUC17 | c.1258T>A p.S420T | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100073466; called by muse, mutect2
- MX1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs377043349; called by mutect2, varscan2
- MYT1L | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101221047, COSV67712558; called by muse, mutect2, varscan2
- NALCN | c.461T>C p.F154S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99215438; called by muse, mutect2, varscan2
- NBEA | c.7006C>A p.L2336I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100080609; called by muse, mutect2
- NBPF3 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs373970730; called by muse, mutect2, varscan2
- NDE1 | c.944T>C p.V315A (on ENST00000577101; = p.G287= on NM_017668.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV100707117; called by muse, mutect2, varscan2
- NEK11 | c.1841A>G p.Q614R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101273058; called by muse, mutect2, varscan2
- NEO1 | c.278T>A p.L93* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV99982140; called by muse, mutect2, varscan2
- NIPBL | c.7220G>A p.R2407Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM148618, COSV56952574; called by muse, mutect2
- NR2E3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs766769900, CM000539; called by muse, mutect2, varscan2
- NR3C1 | c.2236A>G p.S746G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99196330; called by muse, mutect2, varscan2
- NRF1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.983); catalogued as COSV99781825; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs1167519601; called by mutect2, pindel, varscan2
- NRXN2 | c.3686G>A p.R1229H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99634393; called by muse, mutect2, varscan2
- NSG2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1448672133, COSV57459839; called by muse, mutect2, varscan2
- NTSR1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as rs911091935, COSV65138937; called by muse, mutect2
- NUAK1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779923959, COSV54603216, COSV99777043; called by muse, mutect2, varscan2
- NUP205 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1437937080, COSV99607056; called by muse, mutect2, varscan2
- NUP214 | c.5903-1G>T p.X1968_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100845299; called by mutect2, varscan2
- OLFM3 | c.977G>A p.R326Q (on ENST00000338858 / NM_001288821.1; = p.R306Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1278883199, COSV58800476; called by muse, mutect2, varscan2
- OR10K2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs746098545, COSV59221891; called by muse, mutect2, varscan2
- OR51D1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100712380; called by muse, mutect2, varscan2
- OR52K1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs764742409, COSV56904516; called by muse, mutect2, varscan2
- OR5H1 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1033593914, COSV100641710; called by muse, mutect2
- OR5J2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV100399044; called by muse, mutect2, varscan2
- OTUD7B | c.2305T>C p.Y769H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.033); catalogued as COSV100967571; called by mutect2, varscan2
- P3H3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs782481170, COSV51832915; called by muse, mutect2, varscan2
- PABPC1L | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201793065, COSV99407840; called by muse, mutect2, varscan2
- PARS2 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100988304; called by muse, mutect2
- PBX2 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1278122303, COSV100904009; called by muse, mutect2, varscan2
- PCDH10 | c.679del p.Q227Sfs*43 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV52090150; called by pindel, varscan2
- PCDH17 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1254284380, COSV100931409, COSV64974304; called by muse, mutect2
- PCDHA8 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.123); catalogued as COSV65334935; called by muse, mutect2, varscan2
- PCDHB11 | c.1262T>C p.I421T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1270681555, COSV100697019; called by muse, mutect2
- PCDHB4 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99522220; called by muse, mutect2
- PCDHB9 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV53375107; called by muse, mutect2
- PCDHGA7 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs867210871, COSV53906024; called by muse, mutect2, varscan2
- PCNT | c.8737G>T p.D2913Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100855294, COSV100855566; called by muse, mutect2, varscan2
- PEAK1 | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as COSV100432636; called by muse, mutect2, varscan2
- PFKP | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66896529; called by muse, mutect2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHLPP2 | c.1997A>T p.K666I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100673718; called by muse, mutect2, varscan2
- PITX2 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.116); catalogued as rs760317329, COSV100721650; ClinVar: uncertain significance; called by mutect2, varscan2
- PIWIL1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV99806447; called by muse, mutect2, varscan2
- PIWIL2 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.073); catalogued as COSV100769416; called by muse, mutect2, varscan2
- PKDREJ | c.943A>G p.N315D | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99478938; called by muse, mutect2, varscan2
- PKHD1L1 | c.11390T>C p.I3797T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV101006178; called by muse, mutect2, varscan2
- PLEC | c.4273A>C p.T1425P (on ENST00000322810 / NM_201380.4; = p.T1315P on NM_000445.5) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100514579; called by muse, mutect2
- PLEKHA3 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317737; called by muse, mutect2, varscan2
- PNMA1 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99678915; called by muse, mutect2, varscan2
- PNPLA8 | c.661dup p.M221Nfs*8 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs1485361175; called by mutect2, pindel, varscan2
- POGZ | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as rs576546048, COSV99305045; called by mutect2, varscan2
- POT1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs531061783, COSV100714068; ClinVar: uncertain significance; called by mutect2, varscan2
- POU6F1 | c.1652T>C p.F551S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100374818; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP1R12C | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs140838315; called by muse, mutect2
- PPP2R3B | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190359482, COSV101180697; called by muse, mutect2, varscan2
- PRKDC | c.8191C>T p.R2731W | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1275553288, COSV58057530; called by muse, mutect2, varscan2
- PRKDC | c.4142G>A p.S1381N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100040801, COSV58058423; called by muse, mutect2, varscan2
- PRMT3 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100423929; called by muse, mutect2, varscan2
- PTCH1 | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.076); catalogued as rs911494100, COSV100108743; called by muse, mutect2, varscan2
- RACGAP1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs765698830, COSV100407782; called by muse, mutect2, varscan2
- RAD54B | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100279810; called by muse, mutect2
- RAD54L2 | c.3547G>T p.A1183S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.219); catalogued as COSV99621385; called by muse, mutect2, varscan2
- RAPGEF2 | c.3455C>A p.S1152Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100031199; called by muse, mutect2, varscan2
- RAPGEF3 | c.2342G>A p.R781Q (on ENST00000389212; = p.R739Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs767312809, COSV99406388; called by mutect2, varscan2
- RASSF2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.714); catalogued as rs755156690, COSV65081598; called by mutect2, varscan2
- RASSF3 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.82); catalogued as COSV99309429; called by muse, mutect2, varscan2
- RBCK1 | c.278G>A p.G93D (on ENST00000356286 / NM_031229.4; = p.G51D on NM_006462.6) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV100675843; called by muse, mutect2, varscan2
- RBFOX2 | c.268G>A p.A90T (on ENST00000438146 / NM_001349995.2; = p.A20T on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs140420879, COSV53267536; called by muse, mutect2
- RBSN | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs141948895; called by muse, mutect2, varscan2
- RERE | c.2897del p.P966Lfs*4 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs5772316; called by mutect2, pindel, varscan2
- RIMS2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); catalogued as COSV101344493; called by muse, mutect2, varscan2
- RIN3 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99379304; called by muse, mutect2, varscan2
- RNF152 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100455184; called by muse, mutect2, varscan2
- RNF40 | c.1485C>G p.H495Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.836); catalogued as COSV100222118; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROR2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.071); catalogued as COSV65217967; called by muse, mutect2
- RPL7L1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs745431151, COSV100491708; called by muse, mutect2, varscan2
- RWDD2A | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99392393; called by muse, mutect2
- S100A5 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573109, COSV62876752; called by muse, mutect2
- SART1 | c.2368G>A p.G790S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs750824341, COSV100409031; called by muse, mutect2
- SCAF1 | c.2543C>G p.T848S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV62183240; called by muse, mutect2
- SCN9A | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234934110, COSV57599368; called by muse, mutect2
- SCUBE2 | c.2616del p.K873Sfs*5 (on ENST00000649792 / NM_001367977.2; = p.K816Sfs*5 on NM_020974.3) | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs753114269; called by mutect2, pindel, varscan2
- SEC11C | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100231015; called by muse, mutect2
- SELE | c.226A>T p.K76* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100324798; called by muse, mutect2, varscan2
- SEPTIN6 | c.957-1G>C p.X319_splice | Splice Site (SNP) | VAF 40/195 reads (21%) | catalogued as COSV100595625; called by muse, mutect2, varscan2
- SEPTIN8 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99736310; called by muse, mutect2, varscan2
- SERAC1 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100894839; called by muse, mutect2
- SETBP1 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99953445; called by muse, mutect2, varscan2
- SF3B2 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV100488444; called by muse, mutect2, varscan2
- SHARPIN | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1459639778, COSV100075571; called by muse, mutect2
- SHROOM2 | c.3434G>A p.R1145H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1407296841, COSV101099197; called by muse, mutect2
- SIGLEC1 | c.4481C>A p.P1494H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99165874; called by muse, mutect2, varscan2
- SIGLEC1 | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1347392139, COSV52469221; called by muse, mutect2, varscan2
- SKIV2L | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1202090541, COSV100952759; called by muse, mutect2
- SLC13A2 | c.368+1G>A p.X123_splice | Splice Site (SNP) | VAF 12/67 reads (18%) | catalogued as rs1238515903, COSV100120331; called by muse, mutect2, varscan2
- SLC25A41 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV100383074; called by muse, mutect2
- SLC36A1 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99695572; called by muse, mutect2, varscan2
- SLC38A11 | c.683-1G>A p.X228_splice (on ENST00000409149 / NM_001351539.1; = p.X206_splice on NM_173512.2) | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100366677, COSV100366896; called by muse, mutect2
- SLC4A9 | c.1439G>A p.R480H (on ENST00000507527 / NM_001258428.2; = p.R456H on NM_031467.3) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs372321175; called by mutect2, varscan2
- SLC7A5 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as rs1296806721, COSV99879258; called by muse, mutect2, varscan2
- SLC9B1 | c.909del p.F303Lfs*15 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs769618988; called by mutect2, pindel
- SLC9C1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as rs776718397, COSV59890132; called by muse, mutect2, varscan2
- SMARCA2 | c.2614G>A p.V872M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.331); catalogued as COSV100571137; called by muse, mutect2, varscan2
- SMG1 | c.5597C>T p.S1866L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV67169454; called by muse, mutect2, varscan2
- SMOX | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99603223; called by muse, mutect2, varscan2
- SNX25 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV99252901; called by muse, mutect2
- SORCS3 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1564741136, COSV100865177, COSV63803722; called by muse, mutect2, varscan2
- SPACA7 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as rs1001806256, COSV52100847; called by muse, mutect2, varscan2
- SPAM1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772738728, COSV56145566; called by muse, mutect2, varscan2
- SPARC | c.225C>A p.H75Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99163801; called by muse, mutect2, varscan2
- SPART | c.1032A>C p.E344D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV62086754; called by muse, mutect2
- SPON1 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs368233130, COSV59957802; called by muse, mutect2, varscan2
- SPRY1 | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.157); catalogued as COSV100201840; called by muse, mutect2
- SRSF11 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs201985630, COSV100917933, COSV63937524; called by mutect2, varscan2
- SSX5 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as rs782229511, COSV100308753, COSV61255813; called by muse, mutect2, varscan2
- STAT5B | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV99510990; called by muse, mutect2, varscan2
- SUGT1 | c.686T>C p.I229T (on ENST00000343788 / NM_001130912.3; = p.I197T on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100139506; called by muse, mutect2, varscan2
- SUPT6H | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100112444; called by muse, mutect2
- SYNE1 | c.12682C>A p.L4228M (on ENST00000367255 / NM_182961.4; = p.L4157M on NM_033071.3) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV99565894; called by muse, mutect2, varscan2
- TAF9B | c.270+1G>A p.X90_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as COSV100540682; called by muse, mutect2, varscan2
- TAOK3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV101183571; called by muse, mutect2, varscan2
- TARBP1 | c.3405G>C p.K1135N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99241700; called by muse, mutect2, varscan2
- TASOR2 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs200958387, COSV100050538; called by muse, mutect2
- TBP | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100027334; called by muse, mutect2, varscan2
- TCHH | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV100915132; called by muse, mutect2, varscan2
- THAP6 | c.320del p.N107Tfs*38 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | catalogued as rs1334718216; called by mutect2, pindel, varscan2
- THBS3 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as rs1275604735, COSV100366844; called by muse, mutect2, varscan2
- TKTL1 | c.983A>C p.E328A | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.088); catalogued as COSV99473987; called by muse, mutect2
- TMC2 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs777575766, COSV62659571; called by muse, mutect2, varscan2
- TMEM187 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as COSV100890169; called by muse, mutect2, varscan2
- TMEM26 | c.191+2T>C p.X64_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as rs777918034, COSV101051697; called by muse, mutect2, varscan2
- TMEM59L | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as COSV53241684, COSV99450259, COSV99450460; called by muse, mutect2
- TNIK | c.4018C>T p.R1340* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV52673138; called by mutect2, varscan2
- TOPORS | c.1282T>G p.S428A | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV62116441; called by muse, mutect2
- TOR1A | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.271); catalogued as COSV99400175; called by muse, mutect2
- TPTE | c.74C>G p.T25R | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.72); catalogued as rs1034867365; called by muse, mutect2
- TRAF3 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV100693602; called by muse, mutect2, varscan2
- TRAM1 | c.485+1G>A p.X162_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as rs556123107, COSV99140787; called by muse, mutect2, varscan2
- TRIM35 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs754868241, COSV100542789; called by muse, mutect2
- TRIM42 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV53880975, COSV99648392; called by muse, mutect2, varscan2
- TRPM4 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.027); catalogued as COSV99419978; called by muse, mutect2, varscan2
- TRPS1 | c.641C>A p.P214H (on ENST00000220888 / NM_001330599.2; = p.P227H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV99631218; called by muse, mutect2
- TTF2 | c.1278C>T p.S426= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as COSV101037523; called by muse, varscan2
- TUT7 | c.2842del p.Y948Mfs*16 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs751076382; called by mutect2, varscan2
- TXNDC5 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV101124338; called by muse, varscan2
- UBE4A | c.2845C>T p.R949* (on ENST00000252108 / NM_001204077.2; = p.R956* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV52803343; called by muse, mutect2, varscan2
- UBR4 | c.4831A>G p.S1611G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.075); catalogued as COSV100920890; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | catalogued as rs763652408; called by mutect2, varscan2
- UBXN6 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as rs372645367; called by muse, mutect2
- UGT2B17 | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs367742771, COSV58502540; called by muse, mutect2, varscan2
- UNC13B | c.3404C>T p.A1135V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV101036744; called by muse, mutect2, varscan2
- USP2 | c.136_138del p.K46del | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs750299284; called by mutect2, pindel
- USP30 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs868346012, CM1212848, COSV57448013; called by mutect2, varscan2
- USP36 | c.703A>T p.T235S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.872); catalogued as COSV100361521; called by muse, mutect2, varscan2
- USP54 | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs1334442901, COSV60445016, COSV60447193; called by muse, mutect2, varscan2
- USP9X | c.2398C>T p.L800F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100199341; called by muse, mutect2, varscan2
- UXT | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV100243851; called by muse, mutect2
- VEGFC | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV54601029; called by muse, mutect2, varscan2
- VEZF1 | c.1270A>G p.M424V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1394118940, COSV99365745; called by muse, mutect2, varscan2
- VIPR2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.186); catalogued as COSV100057283; called by muse, mutect2, varscan2
- VSIG4 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs201625014, COSV66073066; called by mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1557951659, COSV63058584; called by pindel, varscan2
- WDR90 | c.178A>C p.S60R | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99553476; called by muse, mutect2, varscan2
- WRN | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs62506077; ClinVar: uncertain significance; called by muse, mutect2
- WTAP | c.748A>C p.S250R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs752368470, COSV100603340; called by mutect2, varscan2
- WWC3 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs748994685, COSV101081490; called by muse, mutect2, varscan2
- XIRP2 | c.408+2T>C p.X136_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99743350; called by muse, mutect2, varscan2
- XIRP2 | c.7249dup p.T2417Nfs*3 (on ENST00000628543; = p.T2592Nfs*3 on NM_152381.6) | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | catalogued as rs1171604278; called by mutect2, pindel, varscan2
- XIRP2 | c.8439A>G p.I2813M (on ENST00000628543; = p.I2988M on NM_152381.6) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV99743361; called by muse, mutect2, varscan2
- ZBTB1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1161445906, COSV100704134; called by muse, mutect2
- ZBTB20 | c.484G>A p.V162M (on ENST00000474710 / NM_001164342.2; = p.V89M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV100613956; called by muse, mutect2
- ZC3H12B | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238656617, COSV100161772; called by muse, mutect2
- ZC3H12C | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99584637, COSV99585028; called by muse, mutect2
- ZCWPW2 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101074509, COSV101074650; called by muse, mutect2, varscan2
- ZFP57 | c.529del p.C177Afs*25 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs1272756745; called by pindel, varscan2
- ZFX | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100457732; called by muse, mutect2
- ZFYVE26 | c.6302A>G p.H2101R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs1011165094, COSV100720452; called by muse, mutect2
- ZMYM1 | c.2285A>G p.K762R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100720991; called by muse, mutect2
- ZMYND10 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV99205091; called by muse, mutect2
- ZMYND8 | c.836C>T p.P279L (on ENST00000311275 / NM_001363741.2; = p.P299L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.808); catalogued as rs867343969, COSV99520516; called by muse, mutect2
- ZNF106 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99782656; called by muse, mutect2
- ZNF107 | c.1415A>G p.E472G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100788398; called by muse, mutect2
- ZNF234 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as rs374520249; called by muse, mutect2
- ZNF263 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as rs139107623; called by muse, mutect2, varscan2
- ZNF287 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101209384; called by muse, mutect2, varscan2
- ZNF440 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as rs374917320; called by muse, mutect2, varscan2
- ZNF518B | c.2303C>T p.T768M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs770340215, COSV100456726; called by mutect2, varscan2
- ZNF521 | c.1441T>G p.F481V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV64125830, COSV64130310; called by muse, mutect2, varscan2
- ZNF616 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100348352; called by muse, mutect2, varscan2
- ZNF628 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs1194079684, COSV99220039; called by muse, mutect2, varscan2
- ZNF629 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99354818; called by muse, mutect2, varscan2
- ZNF646 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1384254650, COSV99762349; called by muse, mutect2
- ZNF668 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs746198844, COSV100336686; called by muse, mutect2, varscan2
- ZNF709 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs148352272, COSV67194193, COSV67194671; called by muse, mutect2, varscan2
- ZNF76 | c.433-1G>T p.X145_splice | Splice Site (SNP) | VAF 13/175 reads (7%) | catalogued as COSV99987700; called by muse, mutect2
- ZNF835 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs750603570, COSV73379134; called by muse, mutect2
- ZNF839 | c.2413C>T p.R805C (on ENST00000558850 / NM_001267827.1; = p.R921C on NM_018335.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs573029148, COSV99216264; called by muse, mutect2, varscan2
- ABCC12 | c.1262dup p.S422Ifs*25 | Frame Shift Ins (INS) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- ACTR1A | c.1007_1008del p.R336Tfs*18 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- ADAM9 | c.30del p.T11Pfs*36 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- ADCK5 | c.483del p.E162Sfs*9 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- ADGRA2 | c.1657T>C p.Y553H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2
- AFTPH | c.1241del p.N414Mfs*9 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- ANP32A | c.236del p.G79Afs*15 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, varscan2
- ASH1L | c.1958dup p.P654Afs*6 | Frame Shift Ins (INS) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- ATP10D | c.2050del p.Q684Sfs*22 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- AVL9 | c.608del p.K203Rfs*9 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- BIRC6 | c.5207del p.P1736Qfs*17 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- C19orf12 | c.278del p.P93Lfs*26 (on ENST00000392278 / NM_001031726.3; = p.P82Lfs*26 on NM_031448.6) | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- CACHD1 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.956); called by muse, mutect2
- CD8A | c.528del p.L177Wfs*115 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- CDC23 | c.699dup p.L234Sfs*23 | Frame Shift Ins (INS) | VAF 14/130 reads (11%) | called by mutect2, pindel
- CDC42BPG | c.4627del p.L1543Yfs*14 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- CEPT1 | c.553dup p.C185Lfs*28 | Frame Shift Ins (INS) | VAF 17/143 reads (12%) | called by mutect2, varscan2
- CHAF1B | c.1304del p.P435Lfs*52 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel
- CPLX1 | c.65del p.G22Vfs*73 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- DAPK1 | c.1444del p.L482Cfs*23 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- DCP1B | c.1469dup p.L490Ffs*104 | Frame Shift Ins (INS) | VAF 6/71 reads (8%) | called by mutect2, pindel
- DGKI | c.1865del p.N622Tfs*49 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- ESPL1 | c.1020C>A p.C340* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, varscan2
- FCGBP | c.10526C>A p.P3509H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- FGF2 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2
- GABRD | c.1241del p.G414Afs*95 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- GPR141 | c.690del p.F230Lfs*2 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- HOXA3 | c.884del p.P295Rfs*81 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- ICE1 | c.978del p.F326Lfs*82 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- LTBP2 | c.4224del p.T1409Pfs*82 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- MAL2 | c.169_171del p.S57del | In Frame Del (DEL) | VAF 24/223 reads (11%) | called by pindel, varscan2
- MARK3 | c.459del p.E154Kfs*33 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- MIA3 | c.2977dup p.M993Nfs*3 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- MSH3 | c.1147_1148del p.K383Gfs*20 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by pindel, varscan2*
- MYH2 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- OSMR | c.941del p.N314Ifs*3 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- PHKB | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- PIGZ | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PLXNA1 | c.3051del p.Q1019Rfs*22 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- PRAMEF18 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- PRDM16 | c.2883dup p.R962Qfs*21 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- PSME2 | c.503del p.F168Sfs*17 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, varscan2
- RBM45 | c.1148_1149del p.K383Sfs*4 (on ENST00000616198 / NM_001365579.1; = p.K381Sfs*4 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- RBM6 | c.2678del p.P893Lfs*6 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel
- REV1 | c.316dup p.E106Gfs*40 | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | called by pindel, varscan2
- RFX7 | c.3454del p.I1152* (on ENST00000559447 / NM_001368074.1; = p.I1249* on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- RGS12 | c.3983del p.G1328Afs*13 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- SCLT1 | c.1269del p.A424Qfs*6 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, varscan2
- SERPINB3 | c.347_351+2delinsACAGGTA p.X116_splice | Splice Site (ONP) | VAF 5/34 reads (15%) | called by mutect2*, pindel, varscan2*
- SHMT2 | c.982del p.H328Tfs*8 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- SLC15A4 | c.1031del p.L344Yfs*6 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- SLC25A17 | c.84del p.L30Wfs*42 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.169del p.I57* | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- SMARCA4 | c.810del p.M272Cfs*31 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- SORBS2 | c.1091del p.N364Tfs*25 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- TAGLN3 | c.141del p.G48Afs*9 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- TBX4 | c.847del p.Q283Sfs*55 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- TNK2 | c.952del p.V318* | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.594del p.V199* (on ENST00000343537 / NM_001031685.3; = p.V70* on NM_005426.2) | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- TRGC1 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- TRUB1 | c.595del p.L199Sfs*5 | Frame Shift Del (DEL) | VAF 15/140 reads (11%) | called by mutect2, pindel, varscan2
- TTN | c.28934del p.N9645Tfs*23 (on ENST00000591111; = p.N8718Tfs*23 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- UBE3A | c.472del p.S158Lfs*21 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- YARS1 | c.717_719del p.E239del | In Frame Del (DEL) | VAF 5/35 reads (14%) | called by pindel, varscan2
- ZC3H13 | c.3018del p.K1006Nfs*31 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- ZNF131 | c.433del p.R145Gfs*26 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- ZNF462 | c.6211del p.T2071Hfs*23 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- ABCA8 | c.1329T>C p.S443= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99285895; called by muse, mutect2
- ABCC6 | c.2262C>T p.S754= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs149822534; called by muse, mutect2
- ACKR2 | c.1095T>C p.L365= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99825553; called by muse, mutect2
- ACOT7 | c.306C>A p.A102= (on ENST00000377855 / NM_181864.3; = p.A92= on NM_007274.4) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100830207; called by muse, mutect2, varscan2
- ACTL9 | c.519A>G p.P173= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100185357; called by muse, mutect2, varscan2
- ADAMTS13 | c.3300C>T p.L1100= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs781942887, COSV99390287; called by muse, mutect2, varscan2
- ADAMTS17 | c.2031C>T p.D677= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs199816831; called by muse, mutect2, varscan2
- ADNP2 | c.2460T>C p.F820= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100080904; called by muse, mutect2, varscan2
- ALDH18A1 | c.240C>T p.A80= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1016828034, COSV64662305; ClinVar: likely benign; called by mutect2, varscan2
- AMBN | c.318T>C p.H106= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100534360; called by muse, varscan2
- APPL1 | c.939C>A p.A313= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99897736; called by muse, mutect2
- AQP10 | c.58C>T p.L20= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100270256; called by muse, mutect2, varscan2
- ARID4B | c.3690C>T p.A1230= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs764887423, COSV99935686; called by muse, mutect2, varscan2
- ASAP1 | c.3135C>T p.N1045= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs946391002, COSV100727312; called by muse, mutect2
- ATP13A1 | c.3243C>T p.P1081= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs370704039, COSV52287348; called by muse, mutect2, varscan2
- ATP6V1C1 | c.981T>C p.T327= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV101215007; called by muse, mutect2, varscan2
- ATP7A | c.2178C>T p.F726= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs572956005, COSV58444561; called by muse, mutect2, varscan2
- ATP9A | c.75C>T p.C25= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs781222999, COSV100125032; called by mutect2, varscan2
- ATRN | c.1506C>T p.G502= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs772896328, COSV99497243; called by muse, mutect2
- B3GALT4 | c.285C>T p.G95= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1249643026, COSV101005638; called by muse, mutect2
- BCL2L12 | c.441C>T p.A147= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99881124; called by muse, mutect2
- BMPER | c.1719G>A p.S573= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs773086373, COSV51825790, COSV99779691; called by muse, mutect2, varscan2
- BNIP2 | c.555C>T p.Y185= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99985764; called by muse, mutect2, varscan2
- BPIFB4 | c.1665C>T p.N555= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs751732222, COSV100971532, COSV64951543; called by muse, mutect2, varscan2
- C4orf19 | c.837C>A p.S279= | Silent (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- CACNG3 | c.240C>T p.I80= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs765043632, COSV50066291; called by mutect2, varscan2
- CARMIL2 | c.1764G>T p.S588= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1230223801, COSV100576086; called by muse, mutect2, varscan2
- CBLN1 | c.39G>A p.A13= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs890491768, COSV99535683; called by muse, mutect2
- CCDC39 | c.2028G>A p.R676= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99869068; called by muse, mutect2
- CDHR5 | c.1249C>T p.L417= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV100363516; called by muse, mutect2, varscan2
- CDKL5 | c.489C>T p.G163= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV101184342; called by muse, mutect2
- CDT1 | c.1416G>A p.A472= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1398486473, COSV56347923; called by muse, mutect2
- CEP126 | c.63C>T p.D21= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99681082; called by muse, mutect2, varscan2
- CEP63 | c.480C>T p.R160= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100132773; called by muse, mutect2, varscan2
- CHRM1 | c.789C>T p.C263= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV61007860; called by muse, mutect2, varscan2
- CIR1 | c.993A>G p.K331= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100564992; called by muse, mutect2, varscan2
- CLSTN1 | c.1437C>T p.H479= (on ENST00000377298 / NM_001009566.3; = p.H469= on NM_014944.4) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs775303416, COSV63649839; called by muse, mutect2, varscan2
- CNGA3 | c.519C>T p.T173= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs763964348, COSV55622286; called by muse, mutect2, varscan2
- CPXM1 | c.468C>T p.G156= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs749022279, COSV101013686, COSV66045120; called by muse, mutect2, varscan2
- DACH2 | c.1089T>C p.G363= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs772892123, COSV100913314; called by muse, mutect2, varscan2
- DBF4 | c.1371A>G p.K457= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99719333; called by muse, mutect2
- DEFB118 | c.156A>G p.R52= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99489213; called by muse, mutect2, varscan2
- DGKD | c.708C>T p.H236= (on ENST00000264057 / NM_152879.3; = p.H192= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs748857703, COSV99896440; called by muse, mutect2, varscan2
- DNAH11 | c.12297C>A p.P4099= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100179375; called by muse, mutect2
- DNAH9 | c.12558C>T p.G4186= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs367580113, COSV99306065; called by muse, mutect2, varscan2
- DNAJC6 | c.1308G>A p.S436= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs574045616, COSV54775349, COSV99674321; called by muse, mutect2
- DUSP16 | c.1587G>A p.T529= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs758939939, COSV99963166; called by muse, mutect2, varscan2
- EDN3 | c.462G>A p.R154= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100284950; called by muse, mutect2, varscan2
- ERBB4 | c.3174C>A p.P1058= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- ERGIC1 | c.72C>T p.T24= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs149114698; called by muse, mutect2, varscan2
- EXTL3 | c.2478T>C p.D826= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV99594030; called by muse, mutect2, varscan2
- FBN1 | c.5886T>C p.Y1962= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100355224; called by muse, mutect2, varscan2
- FCRL1 | c.180C>T p.A60= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV63827004; called by muse, mutect2
- FGD5 | c.3411C>T p.N1137= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs926614627, COSV53250914; called by muse, mutect2
- FGFR4 | c.291C>T p.G97= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99449928; called by muse, mutect2, varscan2
- FLVCR1 | c.495C>A p.T165= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100757911; called by muse, mutect2
- FOXRED2 | c.1359G>T p.L453= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99340930; called by muse, mutect2, varscan2
- FSTL5 | c.1962T>C p.Y654= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100056052; called by muse, mutect2
- GALNT18 | c.1185C>T p.T395= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as rs577502852, COSV99924719; called by muse, mutect2
- GMEB2 | c.1401G>A p.T467= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1328508649, COSV99823478, COSV99823676; called by muse, mutect2, varscan2
- GMPR2 | c.843C>T p.G281= (on ENST00000355299 / NM_001351022.2; = p.G299= on NM_016576.5) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs929281874, COSV99945399; called by muse, mutect2, varscan2
- HADHA | c.954C>T p.A318= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs755595692, COSV101023899; called by muse, mutect2, varscan2
- HBB | c.375A>G p.P125= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1445215408, CD951731, COSV100092765; called by mutect2, varscan2
- HIVEP3 | c.5004G>A p.P1668= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs765704017, COSV56021018, COSV99912786; called by muse, mutect2, varscan2
- HMCN1 | c.7551G>A p.G2517= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99625584, COSV99629775; called by mutect2, varscan2
- HPCA | c.99C>T p.G33= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100992182; called by muse, mutect2, varscan2
- HTR5A | c.184C>T p.L62= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99839733; called by muse, mutect2, varscan2
- IBA57 | c.639C>T p.L213= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs751616087, COSV100812776; called by muse, mutect2, varscan2
- IDE | c.2166G>A p.R722= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99794029; called by muse, mutect2
- IGHM | c.372C>T p.F124= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs782517762; called by muse, mutect2
- KCNQ3 | c.2469G>A p.G823= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101196164; called by muse, mutect2
- KDM6B | c.966G>A p.A322= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs199928323, COSV54683496; called by muse, mutect2, varscan2
- KNTC1 | c.3513T>C p.D1171= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100338374; called by muse, mutect2, varscan2
- KPNA3 | c.1326C>T p.A442= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs535292951, COSV55504922; called by muse, mutect2, varscan2
- KRT6B | c.1521A>G p.L507= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1454272819, COSV99360764; called by muse, mutect2
- LRFN4 | c.1245C>T p.T415= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs772966034, COSV100540796; called by muse, mutect2
- LTBP1 | c.4812C>T p.A1604= (on ENST00000404816 / NM_206943.4; = p.A1278= on NM_000627.4) | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs978037436, COSV99698323; called by muse, mutect2, varscan2
- LYST | c.837T>C p.S279= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV101089587; called by muse, mutect2
- MACROD1 | c.378G>A p.P126= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs531482770, COSV99735298; called by muse, mutect2, varscan2
- MAN2A2 | c.399T>C p.T133= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100847875; called by muse, mutect2, varscan2
- MAP3K12 | c.2058A>G p.S686= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99913289; called by muse, mutect2, varscan2
- MCM4 | c.1272G>A p.T424= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs376248536, COSV100031563; called by muse, mutect2, varscan2
- MDP1 | c.249C>A p.L83= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99164628; called by muse, mutect2, varscan2
- MMP12 | c.285C>T p.P95= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs782209734, COSV100404967; called by muse, mutect2, varscan2
- MPPED2 | c.81G>A p.T27= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1214837822, COSV63898154; called by muse, mutect2, varscan2
- MUC6 | c.3933G>A p.S1311= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as rs370204637; called by muse, mutect2
- MYH10 | c.267T>C p.D89= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV99345326; called by muse, mutect2, varscan2
- NDEL1 | c.744T>C p.A248= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as rs1454149912, COSV100233034; called by muse, mutect2, varscan2
- NOS3 | c.1086C>T p.I362= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as rs1021904384, COSV99871691; called by muse, mutect2
- NSD1 | c.3936T>C p.C1312= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100729199; called by muse, mutect2, varscan2
- OR10G3 | c.693A>G p.T231= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100336103; called by muse, mutect2, varscan2
- OR4S2 | c.702C>T p.A234= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100412666; called by muse, mutect2, varscan2
- OR51D1 | c.837T>A p.G279= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100712382; called by muse, mutect2, varscan2
- OR5M10 | c.534C>T p.Y178= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV101595891; called by muse, mutect2
- P2RX5 | c.216C>T p.G72= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs571897312, COSV99835835; called by muse, mutect2, varscan2
- P2RY8 | c.105G>A p.A35= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101184038, COSV67177030; called by muse, mutect2, varscan2
- PAH | c.588C>A p.S196= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100188100; called by muse, mutect2, varscan2
- PARD3 | c.3633C>T p.R1211= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1564407422, COSV61052466; called by muse, mutect2
- PCBP2 | c.291G>A p.P97= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs571129099; called by muse, mutect2, varscan2
- PCDH19 | c.1611C>T p.D537= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as rs766582540, COSV99719910; called by muse, varscan2
- PCDHA5 | c.1971G>A p.P657= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV65350493; called by muse, mutect2, varscan2
- PCDHA7 | c.1287C>T p.D429= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1554135177, COSV65348830; called by muse, mutect2
- PCDHA8 | c.1629G>A p.P543= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs555722520, COSV65333069, COSV65333143; called by muse, mutect2, varscan2
- PCLO | c.10497C>T p.D3499= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1351804286, COSV100433176; called by muse, mutect2, varscan2
- PDZRN3 | c.3156C>T p.D1052= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs749989249, COSV55212272; called by muse, mutect2, varscan2
- PKM | c.852G>T p.L284= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100064857; called by muse, mutect2, varscan2
- PLCH1 | c.72C>T p.S24= (on ENST00000340059 / NM_001130960.2; = p.S36= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs533038760, COSV58188868; called by muse, mutect2, varscan2
- PLEKHG4 | c.450T>C p.P150= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1334485474, COSV100846503; called by muse, mutect2, varscan2
- POGLUT2 | c.201C>T p.G67= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs774195435, COSV99958452; called by mutect2, varscan2
- POSTN | c.1335C>T p.N445= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1318515416, COSV65711900; called by muse, mutect2, varscan2
- POU3F3 | c.939C>T p.D313= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100796864; called by muse, mutect2
- PTCD3 | c.1683C>T p.S561= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99606366; called by muse, mutect2
- PTPN9 | c.1638G>A p.T546= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs371391546; called by muse, mutect2, varscan2
- RAI2 | c.1419C>T p.S473= | Silent (SNP) | VAF 18/299 reads (6%) | catalogued as rs1351856699, COSV58964484, COSV58964693; called by muse, mutect2
- RAP1GDS1 | c.942A>G p.K314= (on ENST00000408927 / NM_001100427.2; = p.K315= on NM_021159.5) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99217018; called by mutect2, varscan2
- RIF1 | c.4014G>A p.V1338= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99690616; called by muse, mutect2, varscan2
- RNF151 | c.333G>A p.T111= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs756282975, COSV100364442; called by muse, mutect2, varscan2
- ROBO1 | c.3327G>A p.V1109= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV101458765; called by muse, mutect2
- RUSC1 | c.2082C>T p.A694= (on ENST00000368352 / NM_001105203.2; = p.A225= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99429868; called by muse, mutect2, varscan2
- SATB1 | c.1995C>T p.D665= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs763259243, COSV100113215; called by muse, mutect2, varscan2
- SERINC4 | c.1419C>T p.C473= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99988432; called by muse, mutect2, varscan2
- SETD4 | c.234T>C p.P78= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs1210579579, COSV100145635; called by muse, mutect2
- SH3TC2 | c.1440T>C p.A480= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100101760; called by muse, mutect2, varscan2
- SLC16A1 | c.279C>T p.G93= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1202792231, COSV100855985; called by muse, mutect2, varscan2
- SLC22A18 | c.819C>A p.A273= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs761341932, COSV100388820, COSV100388924; called by muse, mutect2
- SLC25A36 | c.120G>A p.T40= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs765825580, COSV100149087; called by muse, mutect2, varscan2
- SLC26A7 | c.325T>C p.L109= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV99403451; called by muse, mutect2
- SPAG16 | c.663A>G p.A221= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99793787; called by muse, mutect2
- SUGP2 | c.96C>T p.S32= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs1430406465, COSV54184332; called by muse, mutect2
- SYT17 | c.1395C>T p.R465= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs375022285; called by muse, mutect2, varscan2
- TC2N | c.159T>A p.P53= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100562930; called by muse, mutect2, varscan2
- TLX2 | c.9G>A p.P3= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99283649; called by muse, mutect2
- TLX2 | c.774G>A p.S258= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV52046127; called by muse, mutect2, varscan2
- TM9SF4 | c.1371C>T p.F457= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs757991410, COSV99454581; called by muse, mutect2
- TRIOBP | c.999A>G p.S333= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100730874; called by muse, mutect2
- TSSK6 | c.360C>T p.A120= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs533793681, COSV99389086; called by muse, mutect2, varscan2
- TTLL9 | c.1248C>T p.C416= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs376499277; called by muse, mutect2, varscan2
- UBA6 | c.774A>T p.G258= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs145010992; called by mutect2, varscan2
- UBP1 | c.891A>C p.P297= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV99372701; called by muse, mutect2
- UNC5D | c.2358G>A p.L786= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99775588; called by muse, mutect2, varscan2
- USP5 | c.2457C>T p.Y819= (on ENST00000229268 / NM_001098536.2; = p.Y796= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs200493713, COSV99978651; called by muse, mutect2, varscan2
- VCAN | c.5598A>C p.V1866= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV54112693, COSV99425965; called by muse, mutect2, varscan2
- WDR4 | c.1179G>A p.P393= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs759460966, COSV100375438, COSV57734516; called by muse, mutect2, varscan2
- ZFHX4 | c.810C>T p.S270= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs369214100; called by mutect2, varscan2
- ZFPM2 | c.1398T>G p.S466= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101023236, COSV65872815, COSV65874990; called by muse, mutect2
- ZIC1 | c.174G>A p.S58= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs755293143, COSV51558925; called by muse, mutect2, varscan2
- ZIC4 | c.489C>T p.V163= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1437492053, COSV101267987; called by muse, mutect2, varscan2
- ZNF224 | c.1083G>A p.T361= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs1158565284, COSV61242654; called by muse, mutect2
- ZNF345 | c.1023T>G p.P341= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100080297, COSV100080312; called by muse, mutect2, varscan2
- ZNF440 | c.528A>G p.V176= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as COSV100407551; called by muse, mutect2, varscan2
- ZNF462 | c.5757G>A p.Q1919= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99472108; called by muse, mutect2, varscan2
- ZNF497 | c.669C>T p.C223= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs763021511, COSV54050547; called by muse, mutect2, varscan2
- ZNF594 | c.837T>C p.S279= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs1344495842, COSV101280497, COSV101280507; called by muse, mutect2
- ZNF595 | c.1302C>T p.N434= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100227712; called by muse, mutect2, varscan2
- ZNF618 | c.1767C>T p.R589= (on ENST00000374126 / NM_001318042.2; = p.R496= on NM_133374.2) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs372911485; called by muse, mutect2
- ZRANB1 | c.903C>A p.R301= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100669215; called by muse, mutect2
- ZSCAN2 | c.912G>A p.K304= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100306903; called by muse, mutect2, varscan2
- ACAA2 | chr18:49814330 G>A | 5'Flank (SNP) | VAF 5/50 reads (10%) | catalogued as rs1298013417; called by muse, mutect2
- ARAP1 | c.748-22G>A | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs377132787; called by muse, mutect2, varscan2
- DCHS2 | n.7559del | RNA (DEL) | VAF 6/45 reads (13%) | catalogued as CD1514800; called by mutect2, pindel, varscan2
- ELP4 | c.1147-19903_1147-19902del | Intron (DEL) | VAF 7/73 reads (10%) | catalogued as rs777078963; called by pindel, varscan2
- LINC02870 | n.395G>A | RNA (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- MIR1251 | n.24C>T | RNA (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- MTCL1 | c.2968-3227G>C | Intron (SNP) | VAF 12/98 reads (12%) | catalogued as rs770336713, COSV60406210; called by muse, mutect2, varscan2
- NR1I3 | c.*46A>G | 3'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100915720; called by muse, mutect2, varscan2
- OPN4 | c.291-812A>G | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99618420; called by muse, mutect2, varscan2
- RBM44 | chr2:237813618 C>A | 5'Flank (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100389897; called by mutect2, varscan2
- RPL10 | chrX:154403356 C>T | 3'Flank (SNP) | VAF 11/42 reads (26%) | catalogued as rs782185212, COSV50011637; called by muse, mutect2, varscan2
- SNORD109A | n.18A>G | RNA (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- THSD4 | c.1016-70254T>C | Intron (SNP) | VAF 12/128 reads (9%) | catalogued as rs751580539; called by muse, mutect2
- TTN | c.10360+1136C>A | Intron (SNP) | VAF 17/159 reads (11%) | catalogued as COSV100615062; called by muse, varscan2
- UGT1A6 | c.862-23187G>A | Intron (SNP) | VAF 11/75 reads (15%) | catalogued as rs771949487, COSV100530310; called by muse, mutect2, varscan2
- VMP1 | c.*1380T>G | 3'UTR (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
